Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8DD, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8DD-01A (Primary Tumor).

[page 1 of 2]
Operative Procedure:
Sternotomy, mediastinal mass dissection.

Specimen Received:
Anterior mediastinal mass

Final Pathologic Diagnosis:

Anterior mediastinal mass, excision:

Thymoma, lymphocyte predominant type (thymoma type B1).

Specimen: Anterior mediastinal mass

Procedure: Excision of anterior mediastinal mass

Specimen integrity: Intact specimen

Specimen weight: 274 g

Tumor size: 8.2 cm (greatest dimension)

Histologic type: Lymphocyte predominant (type B1)

Tumor extension: Tumor focally extends through the fibrous capsule (in section 2).

Margins:

Margins uninvolved by tumor

Distance of tumor from closest margin: 0.2 mm

Treatment effect: Not applicable

Lymphovascular invasion: Not identified.

Regional lymph nodes: Present

Number examined: 9

Number involved: 0

Pathologic Staging for Thymomas (Modified Masaoka Stage)

Stage IIa: Microscopic transcapsular invasion

Implants/distant metastasis: Cannot be assessed

Additional pathologic findings: None.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

The specimen is received fresh for tissue procurement with acquisition of tissue labeled with the patient's name, and labeled "anterior mediastinal mass" and consists of a previously inked and multiply incised irregular, lobulated rubbery mass, which has dimensions of 8.2 x 7.4 x 5.8 cm and weighs 274 g. The external surface is gray-tan to red-brown, smooth and glistening to somewhat shaggy. There is some loosely attached fat/possible thymic tissue, which has dimensions of 12.0 x 7.0 x 2.0 cm. The specimen is further sectioned to reveal a pink-tan to red-brown, lobulated, glistening, focally hemorrhagic and somewhat fleshy appearing cut surface. This mass is largely encapsulated. The loosely attached fat/possible thymic tissue is

ICD-O-3
Thymoma, type B1, malignant 8583/3
Site: Thymus C379
Mediastinum, anterior C38.1
JW 6/13/14

[page 2 of 2]
serially sectioned to reveal a gray-yellow to red-brown, focally hemorrhagic, lobulated, glistening cut surface. Also, there are eight discrete lymph nodes identified that range from 0.4 to 1.9 cm in greatest dimension.

Representative sections are submitted as labeled:

- 1-4 mass (two diagnostic sections are submitted in each cassette);
- 5 loosely attached fat/possible thymic tissue;
- 6 four lymph nodes submitted in toto;
- 7 one lymph node submitted in toto;
- 8 three lymph nodes submitted in toto.

Microscopic Description:

Sections show an encapsulated tumor composed of abundant small mature lymphocytes in association with inconspicuous bands of epithelial cells with small oval nuclei and scant cytoplasm. There are broad fibrous bands running through the tumor which intersect at acute angles. There are occasional "serum lakes", hypocellular zones with protein-containing fluid.

Surgical Pathology Report

Taken: DOB: Gender: F

Source: NCI Genomic Data Commons file e396fedd-0910-47bf-9d3e-c6f7eee62e4c (TCGA-X7-A8DD.C4324862-7C03-45FC-81EC-8FC9B357D43E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).